CCDI case PBCLFY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f3849850-3e52-4b61-870d-7cc30fc4ab04

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Germinoma: ICD-O-3 morphology code: 9064/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.1 years (6,235 days).

Biospecimens (3 samples)
- Sample 0DUMDO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUMDV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUME5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
